Somatic mutation profile of tumor specimen TCGA-44-2656-01A (aliquot TCGA-44-2656-01A-02W-0928-08) from TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.6 years (21,766 days).
Specimen TCGA-44-2656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a55ad7e-8bb0-4260-9eb9-1f12ae28e24c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2656-10A (Blood Derived Normal), aliquot TCGA-44-2656-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/132cd160-b702-47f4-a6a7-6e9c02c26586

The open-access MAF lists 829 somatic variants for this specimen: 647 protein-altering or splice-affecting, 168 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 541, Silent 168, Nonsense Mutation 55, Splice Site 21, Frame Shift Del 11, Splice Region 10, Frame Shift Ins 6, Intron 5, RNA 4, 5'UTR 2, In Frame Del 1, Nonstop Mutation 1.

Variants (750 of 829; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 119/294 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV50957947; called by muse, mutect2, varscan2
- AADACL2 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 137/487 reads (28%) | catalogued as COSV62929677; called by muse, mutect2, varscan2
- ABCA10 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as COSV52218722; called by muse, mutect2, varscan2
- ABCA13 | c.12366G>T p.K4122N | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV71284197; called by muse, mutect2, varscan2
- ABCA4 | c.426C>A p.H142Q | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV64671523; called by muse, mutect2, varscan2
- ABCA9 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60621424, COSV60627170; called by muse, mutect2, varscan2
- ABCC9 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV53964291; called by muse, mutect2, varscan2
- ACSL1 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55661049, COSV55666266; called by muse, mutect2, varscan2
- ACTG1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV59509545, COSV59509810; called by muse, varscan2
- ADAM12 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64103177, COSV64103261; called by muse, mutect2, varscan2
- ADAM20 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 94/628 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV56454240; called by muse, mutect2, varscan2
- ADAMTS12 | c.1891C>T p.H631Y | Missense Mutation (SNP) | VAF 22/608 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV61256826; called by muse, mutect2
- ADAMTS16 | c.3591C>A p.C1197* | Nonsense Mutation (SNP) | VAF 48/176 reads (27%) | catalogued as COSV56980510; called by muse, mutect2, varscan2
- ADCY5 | c.1909A>T p.I637F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59194995; called by muse, mutect2, varscan2
- ADCY6 | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57166513; called by muse, mutect2, varscan2
- ADGRG4 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 160/407 reads (39%) | catalogued as rs1433246655, COSV54950883; called by muse, mutect2, varscan2
- ADGRL4 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66059758; called by muse, mutect2, varscan2
- AFF2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 231/551 reads (42%) | catalogued as COSV60656743, COSV60659025; called by muse, mutect2, varscan2
- AFF4 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 43/149 reads (29%) | catalogued as COSV54792178; called by muse, mutect2, varscan2
- AGL | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54048722, COSV54054032; called by muse, mutect2, varscan2
- AGO3 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV55791675; called by muse, mutect2, varscan2
- AHNAK2 | c.14074G>A p.E4692K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV60909243; called by muse, mutect2, varscan2
- ALDH1L1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56411309; called by muse, mutect2, varscan2
- ALK | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV66559553; called by muse, mutect2
- ALMS1 | c.11863T>G p.S3955A | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.059); catalogued as rs45528134; called by muse, mutect2, varscan2
- ALOX5 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65551322; called by muse, mutect2
- ALPK2 | c.3485C>A p.A1162D | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV100864754, COSV64490735; called by muse, mutect2, varscan2
- APOB | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51925712; called by muse, mutect2
- APOBEC4 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58016983; called by muse, mutect2, varscan2
- APOBR | c.2839G>T p.A947S (on ENST00000431282; = p.A956S on NM_018690.4) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1486024392, COSV60489064; called by muse, mutect2, varscan2
- ARFIP1 | c.567G>T p.M189I (on ENST00000353617 / NM_001287432.1; = p.M157I on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV61883385, COSV61886434; called by muse, mutect2, varscan2
- ARHGAP25 | c.1380C>A p.S460R (on ENST00000409202 / NM_001007231.3; = p.S452R on NM_014882.3) | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.348); catalogued as COSV54899273; called by muse, mutect2, varscan2
- ARHGAP33 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as rs139022184; called by mutect2, varscan2
- ARMC5 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51655112; called by muse, mutect2, varscan2
- ARSF | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63839074; called by muse, varscan2
- ASB15 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99306291; called by muse, mutect2, varscan2
- ASPM | c.8315A>G p.Q2772R | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54125763; called by muse, mutect2, varscan2
- ASTL | c.216C>G p.F72L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.525); catalogued as COSV60903665; called by muse, mutect2, varscan2
- ATP1A3 | c.2892G>T p.E964D (on ENST00000545399 / NM_001256214.2; = p.E951D on NM_152296.5) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV57485662; called by muse, mutect2, varscan2
- ATP1B4 | c.844A>G p.I282V (on ENST00000218008 / NM_001142447.3; = p.I278V on NM_012069.5) | Missense Mutation (SNP) | VAF 143/393 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV54311501; called by muse, mutect2, varscan2
- ATP2B3 | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV54841452; called by muse, mutect2, varscan2
- ATP4A | c.2542C>A p.R848S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52866115; called by muse, mutect2
- ATXN1 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as COSV55207197, COSV55209691; called by muse, mutect2, varscan2
- BABAM2 | c.851+1G>T p.X284_splice | Splice Site (SNP) | VAF 20/266 reads (8%) | catalogued as COSV59617839, COSV59626067; called by muse, mutect2
- BCAS1 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65084225; called by muse, mutect2, varscan2
- BCAS1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as COSV65084231; called by muse, mutect2, varscan2
- BDP1 | c.1961A>T p.H654L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs754948193, COSV62429287; called by muse, mutect2, varscan2
- BICD1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55675492, COSV55683113; called by muse, mutect2
- BIN2 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 152/460 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57203914; called by muse, mutect2, varscan2
- BLOC1S4 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV57900861, COSV57901018; called by muse, mutect2
- BORA | c.853T>A p.S285T (on ENST00000613797; = p.S210T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.709); catalogued as COSV64694931; called by muse, mutect2, varscan2
- BRINP3 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 67/390 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66515010; called by muse, mutect2, varscan2
- BRIP1 | c.3601A>G p.I1201V | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1396175226, COSV51994991; called by muse, mutect2, varscan2
- BUB1B | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 87/301 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs587778144, COSV55010377; ClinVar: not provided; called by muse, mutect2, varscan2
- C1orf116 | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV63943796; called by muse, mutect2, varscan2
- C22orf42 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.567); catalogued as COSV66075359; called by muse, mutect2, varscan2
- C2orf78 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.52); catalogued as COSV68516564; called by muse, mutect2, varscan2
- C7 | c.1814T>A p.L605H | Missense Mutation (SNP) | VAF 54/1096 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57471632; called by muse, mutect2
- C8B | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV64776652; called by muse, mutect2, varscan2
- C9orf64 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV59032188; called by muse, mutect2, varscan2
- CACNA1E | c.1924A>C p.T642P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62384172; called by muse, mutect2, varscan2
- CACNA1E | c.5791G>T p.G1931C | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV62383371, COSV62384187; called by muse, mutect2, varscan2
- CADPS | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV51869717; called by muse, mutect2, varscan2
- CALU | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV50823286, COSV99975725; called by muse, mutect2, varscan2
- CAMK4 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 101/440 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56663808; called by muse, mutect2, varscan2
- CAMTA1 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); catalogued as rs1335374168, COSV57884758; called by muse, mutect2
- CARD11 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 98/676 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62716163, COSV62716582; called by muse, mutect2, varscan2
- CCDC136 | c.1894C>A p.Q632K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52796854; called by muse, mutect2, varscan2
- CCDC171 | c.2564A>C p.K855T | Missense Mutation (SNP) | VAF 151/612 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52634882; called by muse, mutect2, varscan2
- CCDC63 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV57527263; called by muse, mutect2, varscan2
- CCT8L2 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV63461753, COSV63464025; called by muse, mutect2, varscan2
- CD163 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775730, COSV63131323; called by muse, mutect2, varscan2
- CD163 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775731; called by muse, mutect2, varscan2
- CD244 | c.785C>A p.T262N (on ENST00000368033 / NM_001166663.2; = p.T257N on NM_016382.4) | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs1377239214, COSV59236441; called by muse, mutect2, varscan2
- CD244 | c.403G>T p.E135* (on ENST00000368033 / NM_001166663.2; = p.E130* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 25/150 reads (17%) | catalogued as COSV59236463, COSV59237862; called by muse, mutect2, varscan2
- CD5L | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 81/304 reads (27%) | catalogued as COSV63821247; called by muse, mutect2, varscan2
- CDC73 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.045); catalogued as COSV66465322; called by muse, mutect2
- CDH1 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV55728592; called by muse, mutect2, varscan2
- CDH12 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66390889; called by muse, mutect2
- CDH6 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV54065290; called by muse, mutect2
- CEACAM18 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67282317, COSV67283582; called by muse, mutect2, varscan2
- CEP126 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV54822265; called by muse, mutect2, varscan2
- CFAP299 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871884; called by muse, mutect2, varscan2
- CFAP57 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV52539439; called by muse, mutect2, varscan2
- CFHR4 | c.249C>A p.C83* (on ENST00000367416 / NM_001201551.2; = p.C84* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 123/409 reads (30%) | catalogued as COSV52225316; called by muse, mutect2, varscan2
- CFHR5 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56818614; called by muse, mutect2, varscan2
- CHST13 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV60041502; called by muse, mutect2, varscan2
- CIP2A | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417434; called by muse, mutect2, varscan2
- CIT | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 150/363 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55861941; called by muse, mutect2, varscan2
- CLASP1 | c.4265A>T p.Q1422L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV55315566; called by muse, mutect2, varscan2
- CLCN4 | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66465375; called by muse, mutect2
- CLDN14 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772018; called by muse, mutect2, varscan2
- CNGB3 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 60/210 reads (29%) | catalogued as COSV60685706; called by muse, mutect2, varscan2
- CNTN2 | c.2914C>A p.P972T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV59348479; called by muse, mutect2, varscan2
- CNTN4 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV61868879; called by muse, mutect2, varscan2
- CNTNAP2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 152/509 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62150646; called by muse, mutect2, varscan2
- CNTNAP4 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs762920106, COSV100269809; called by muse, mutect2, varscan2
- CNTNAP4 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100269812; called by muse, mutect2, varscan2
- CNTNAP5 | c.3214G>A p.G1072R | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs772641478, COSV70475477; called by muse, mutect2, varscan2
- COBL | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54339812; called by muse, mutect2, varscan2
- COL11A1 | c.4985C>A p.S1662* | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | catalogued as COSV62174875, COSV62191256; called by muse, mutect2, varscan2
- COL15A1 | c.3032-1G>T p.X1011_splice | Splice Site (SNP) | VAF 24/380 reads (6%) | catalogued as COSV66641776; called by muse, mutect2
- COL25A1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67647040; called by muse, mutect2
- COL27A1 | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV61922285; called by muse, mutect2, varscan2
- COL3A1 | c.282+1G>T p.X94_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58582976; called by muse, mutect2, varscan2
- COL4A2 | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV64625481; called by muse, mutect2, varscan2
- COL5A1 | c.1306del p.A436Rfs*122 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | catalogued as COSV65668523; called by mutect2, pindel, varscan2
- COL5A1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65665879; called by muse, mutect2, varscan2
- COL5A2 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.781); catalogued as COSV100880708, COSV66407652; called by muse, mutect2, varscan2
- CPEB1 | c.1621C>T p.Q541* (on ENST00000617958; = p.Q476* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/147 reads (20%) | catalogued as COSV55617442; called by muse, mutect2, varscan2
- CPED1 | c.2839C>A p.Q947K | Missense Mutation (SNP) | VAF 267/825 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100120269; called by muse, mutect2, varscan2
- CRACD | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV51716175; called by muse, mutect2, varscan2
- CREB3L2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV57792636; called by muse, mutect2, varscan2
- CRISPLD1 | c.1231T>A p.S411T | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV51544994; called by muse, mutect2
- CRISPLD2 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52277138; called by muse, mutect2, varscan2
- CROT | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58973012; called by muse, mutect2, varscan2
- CSMD2 | c.9173G>T p.W3058L | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53885674; called by muse, mutect2
- CSMD2 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as COSV53885699, COSV53897184; called by muse, mutect2, varscan2
- CSMD3 | c.10628G>T p.G3543V (on ENST00000297405 / NM_001363185.1; = p.G3374V on NM_052900.3) | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52115921, COSV99834043; called by muse, mutect2
- CSMD3 | c.9230C>T p.T3077I (on ENST00000297405 / NM_001363185.1; = p.T2908I on NM_052900.3) | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV52115937; called by muse, mutect2
- CSMD3 | c.4107A>T p.Q1369H (on ENST00000297405 / NM_001363185.1; = p.Q1265H on NM_052900.3) | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV52116030; called by muse, mutect2, varscan2
- CSMD3 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52116072; called by muse, mutect2
- CSN3 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV59243600; called by muse, mutect2, varscan2
- CT83 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 185/378 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV64140819; called by muse, mutect2, varscan2
- CTNNA2 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 127/643 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100559222, COSV58138215; called by muse, mutect2, varscan2
- CTNND2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV58869546; called by muse, mutect2, varscan2
- CUBN | c.10429C>A p.P3477T | Missense Mutation (SNP) | VAF 125/464 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1468596216, COSV64709163; called by muse, mutect2, varscan2
- CUBN | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV64702053; called by muse, mutect2, varscan2
- CYP4F3 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55407556; called by muse, mutect2, varscan2
- DCAF8L1 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV71595155; called by muse, mutect2, varscan2
- DCUN1D1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV53043841; called by muse, mutect2, varscan2
- DDC | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 104/329 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63564084; called by muse, mutect2, varscan2
- DENND1A | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 66/695 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV65323094; called by muse, mutect2, varscan2
- DEPDC7 | c.1263G>A p.K421= (on ENST00000241051 / NM_001077242.2; = p.K412= on NM_139160.2) | Splice Region (SNP) | VAF 23/139 reads (17%) | catalogued as COSV53806054; called by muse, mutect2, varscan2
- DGKB | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 348/1108 reads (31%) | catalogued as COSV51765416; called by muse, mutect2, varscan2
- DIO2 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs766090858, COSV70444863, COSV70445145; called by muse, mutect2, varscan2
- DIP2C | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55148506; called by muse, mutect2, varscan2
- DISP3 | c.3376-1G>T p.X1126_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53821800; called by muse, mutect2
- DLL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV52693610; called by muse, mutect2
- DNAH9 | c.9245A>T p.Q3082L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52337591; called by muse, mutect2, varscan2
- DNER | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59161139; called by muse, mutect2
- DSCAML1 | c.1894G>T p.E632* (on ENST00000321322; = p.E572* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV58383444; called by muse, mutect2, varscan2
- DSG3 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV57124603; called by muse, mutect2
- DUOX1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV58477926; called by muse, mutect2, varscan2
- DUSP22 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60524272; called by muse, mutect2
- DYNC1H1 | c.6397G>T p.E2133* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV64134814; called by muse, mutect2, varscan2
- DYRK4 | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50537998; called by muse, mutect2, varscan2
- EBF2 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV68776392, COSV68779949; called by muse, mutect2, varscan2
- EDA2R | c.264C>T p.P88= | Splice Region (SNP) | VAF 20/51 reads (39%) | catalogued as COSV53630426; called by muse, mutect2, varscan2
- EDIL3 | c.1398G>C p.R466S | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV56882919; called by muse, mutect2, varscan2
- EDN3 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs142051051, COSV61107321; called by muse, mutect2, varscan2
- EIF4A2 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV56215789; called by muse, mutect2, varscan2
- ELF1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV53497380; called by muse, mutect2, varscan2
- ELF2 | c.599C>G p.P200R (on ENST00000379550 / NM_001331036.2; = p.P140R on NM_006874.4) | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55491915; called by muse, mutect2, varscan2
- EMILIN2 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV54421597; called by muse, mutect2, varscan2
- ENAH | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV52865586, COSV52868416; called by muse, mutect2, varscan2
- EPHA5 | c.2188C>A p.Q730K | Missense Mutation (SNP) | VAF 167/887 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56633773; called by muse, mutect2, varscan2
- EPHA6 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 210/867 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV67561544; called by muse, mutect2, varscan2
- EPHA7 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65178175; called by muse, mutect2, varscan2
- EPX | c.171-2A>T p.X57_splice | Splice Site (SNP) | VAF 59/402 reads (15%) | catalogued as COSV56595278; called by muse, mutect2, varscan2
- EPYC | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798686, COSV53800095; called by muse, mutect2, varscan2
- ERG | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55727958; called by muse, mutect2, varscan2
- ERICH3 | c.604-1G>C p.X202_splice | Splice Site (SNP) | VAF 26/535 reads (5%) | catalogued as COSV58600961; called by muse, mutect2
- ETNPPL | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56594815, COSV56595625; called by muse, mutect2, varscan2
- EXOC5 | c.1600A>C p.T534P | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV61770256; called by muse, mutect2
- EXT2 | c.1654G>T p.G552C (on ENST00000343631; = p.G585C on NM_000401.3) | Missense Mutation (SNP) | VAF 84/470 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640528, COSV59146368; called by muse, mutect2, varscan2
- EXT2 | c.1655G>T p.G552V (on ENST00000343631; = p.G585V on NM_000401.3) | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100640529; called by muse, mutect2, varscan2
- F13A1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 110/507 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV53554408; called by muse, mutect2, varscan2
- F8 | c.4996C>T p.Q1666* | Nonsense Mutation (SNP) | VAF 27/464 reads (6%) | catalogued as COSV64270193; called by muse, mutect2
- FAM120A | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52901843, COSV99464656; called by muse, mutect2
- FAM171B | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 122/453 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV59001183; called by muse, mutect2, varscan2
- FAM47C | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63724173, COSV63727538; called by muse, mutect2, varscan2
- FAM47C | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.519); catalogued as rs1251517581, COSV63724190; called by muse, mutect2, varscan2
- FAM83C | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV65582262, COSV65584138; called by muse, mutect2, varscan2
- FBN2 | c.4862G>A p.C1621Y | Missense Mutation (SNP) | VAF 32/1150 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52496462, COSV52547611; called by muse, mutect2
- FCRL4 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54860250; called by muse, mutect2, varscan2
- FCRLA | c.296C>A p.S99Y (on ENST00000367959; = p.S76Y on NM_032738.4) | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99375736; called by muse, varscan2
- FER1L6 | c.4814C>A p.T1605N | Missense Mutation (SNP) | VAF 173/462 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV67548408; called by muse, mutect2, varscan2
- FHDC1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV52598100; called by muse, mutect2, varscan2
- FHL1 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 146/358 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV61779961; called by muse, mutect2, varscan2
- FHL5 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV58735599; called by muse, mutect2, varscan2
- FLG | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs779204654, COSV64237807; called by muse, mutect2, varscan2
- FRAS1 | c.5948T>A p.L1983Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53593821; called by muse, mutect2
- FREM1 | c.4389G>T p.Q1463H | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV66518765; called by muse, mutect2, varscan2
- FRMPD2 | c.922-2A>T p.X308_splice | Splice Site (SNP) | VAF 14/120 reads (12%) | catalogued as COSV59715779; called by muse, mutect2, varscan2
- FRY | c.5921A>T p.E1974V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV66566181; called by muse, mutect2, varscan2
- FSIP2 | c.18260C>A p.S6087Y | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100554334; called by muse, mutect2, varscan2
- FUT8 | c.611G>C p.C204S (on ENST00000360689 / NM_001371534.1; = p.C41S on NM_004480.4) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61280796; called by muse, mutect2, varscan2
- FYCO1 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56114071; called by muse, mutect2, varscan2
- GAK | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV58503188; called by muse, mutect2, varscan2
- GALC | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 50/615 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54323602; called by muse, mutect2
- GALNT3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 21/675 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV67061422; called by muse, mutect2
- GANAB | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 137/527 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60462469; called by muse, mutect2, varscan2
- GARNL3 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59224143; called by muse, mutect2
- GAS2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53404911; called by muse, mutect2, varscan2
- GBP1 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV65082737; called by muse, mutect2
- GDNF | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 149/517 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV58478486; called by muse, mutect2, varscan2
- GJB1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM066092, COSV62139558; called by muse, mutect2, varscan2
- GLDC | c.2851T>C p.S951P | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58677039; called by muse, mutect2
- GLRX3 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 70/217 reads (32%) | catalogued as COSV58691719; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAQ | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 214/951 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54108142; called by muse, mutect2, varscan2
- GPC5 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV65581502, COSV65582941; called by muse, mutect2, varscan2
- GPR139 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV58501876; called by muse, mutect2
- GPR141 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 143/785 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57731470; called by muse, mutect2, varscan2
- GPR63 | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs866908729, COSV57739865; called by muse, mutect2, varscan2
- GPR63 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 138/603 reads (23%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1168525347, COSV57739874; called by muse, mutect2, varscan2
- GRID1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 92/228 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60016391, COSV60052524; called by muse, mutect2, varscan2
- GRIN2D | c.2480T>A p.I827N | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53517920; called by muse, mutect2, varscan2
- GRM8 | c.2096C>A p.T699N | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV58807197; called by muse, mutect2, varscan2
- GRM8 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58807209, COSV58878853; called by muse, mutect2
- GTF3C1 | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 28/774 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.864); catalogued as COSV62239353; called by muse, mutect2
- HAS2 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 38/744 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV58262359; called by muse, mutect2
- HDAC2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 108/382 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64037464; called by muse, mutect2, varscan2
- HDAC4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV61860646; called by muse, mutect2, varscan2
- HEATR5A | c.4460C>A p.A1487E | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs757014948, COSV66338870; called by muse, mutect2, varscan2
- HECW1 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 221/693 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as COSV67823496; called by muse, mutect2, varscan2
- HEMGN | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV52325428; called by muse, mutect2, varscan2
- HEPH | c.1557G>T p.W519C (on ENST00000343002; = p.W252C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960018; called by muse, mutect2, varscan2
- HHATL | c.1011G>T p.T337= | Splice Region (SNP) | VAF 8/45 reads (18%) | catalogued as COSV55133017; called by muse, mutect2, varscan2
- HLA-DPA1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs190707736, COSV70088347; called by muse, mutect2
- HMCN1 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV54881632; called by muse, mutect2, varscan2
- HNF4G | c.1104C>A p.I368= (on ENST00000354370 / NM_001330561.2; = p.I415= on NM_004133.5) | Splice Region (SNP) | VAF 20/214 reads (9%) | catalogued as COSV62966208; called by muse, mutect2, varscan2
- HNRNPD | c.777del p.K260Rfs*109 (on ENST00000313899 / NM_031370.3; = p.K260Rfs*60 on NM_002138.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 107/597 reads (18%) | catalogued as COSV100002762; called by mutect2, varscan2
- HOXA1 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as COSV56065371; called by muse, mutect2, varscan2
- HOXA2 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as rs1278253439, COSV56065380; called by muse, mutect2, varscan2
- HOXA7 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV54216847, COSV99636727; called by muse, mutect2, varscan2
- HP1BP3 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391598; called by muse, mutect2, varscan2
- HSPH1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.313); catalogued as COSV60710458; called by muse, mutect2, varscan2
- IFNA2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.359); catalogued as COSV66505368, COSV66505777; called by muse, mutect2
- IGFBPL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186519875, COSV66617825; called by muse, mutect2, varscan2
- IGHV3-33 | c.215A>C p.Y72S | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.005); catalogued as rs187379689; called by muse, mutect2
- IGLON5 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as rs201159850, COSV54534813; called by muse, mutect2, varscan2
- IGSF10 | c.7490C>A p.T2497K | Missense Mutation (SNP) | VAF 146/471 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56370576; called by muse, mutect2, varscan2
- IGSF10 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 138/465 reads (30%) | catalogued as COSV56782276, COSV56792468; called by muse, mutect2, varscan2
- IGSF5 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66029450; called by muse, mutect2, varscan2
- IL17F | c.5C>A p.T2K | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV60233731; called by muse, mutect2
- INSL5 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs778970586, COSV58787976; called by muse, mutect2, varscan2
- INTU | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 53/253 reads (21%) | catalogued as COSV58869828; called by muse, mutect2, varscan2
- IPO8 | c.3020C>A p.A1007E | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV56239193, COSV56239949; called by muse, mutect2, varscan2
- IPO8 | c.323+1G>T p.X108_splice | Splice Site (SNP) | VAF 79/287 reads (28%) | catalogued as COSV56239957, COSV56244872; called by muse, mutect2, varscan2
- IQGAP2 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 76/396 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs369302838, COSV57168962; called by muse, mutect2, varscan2
- ISLR | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs780036106, COSV51433111; called by muse, mutect2, varscan2
- ISOC1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240441068, COSV51491188; called by muse, mutect2, varscan2
- ITGA2B | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV52231435; called by muse, mutect2, varscan2
- ITIH2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs141514196; called by muse, mutect2, varscan2
- JMY | c.2528G>T p.R843I | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV68659603; called by muse, mutect2, varscan2
- KAT6B | c.1993+1G>T p.X665_splice | Splice Site (SNP) | VAF 25/127 reads (20%) | catalogued as COSV54743082; called by muse, mutect2, varscan2
- KATNAL1 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 85/538 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66062713; called by muse, mutect2, varscan2
- KCNA4 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV60250931; called by muse, mutect2, varscan2
- KCNH1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 150/516 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55071630; called by muse, mutect2, varscan2
- KDM3A | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs895391110, COSV57218783; called by muse, mutect2, varscan2
- KDM3A | c.3685C>T p.Q1229* | Nonsense Mutation (SNP) | VAF 74/721 reads (10%) | catalogued as COSV57218054, COSV57218797; called by muse, mutect2, varscan2
- KIAA0895 | c.472G>T p.V158L (on ENST00000297063 / NM_001100425.2; = p.V107L on NM_015314.3) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV51709169; called by muse, mutect2, varscan2
- KIAA1109 | c.12352G>T p.G4118C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV52664312; called by muse, mutect2, varscan2
- KIAA1549L | c.1835C>A p.T612N (on ENST00000321505; = p.T909N on NM_012194.3) | Missense Mutation (SNP) | VAF 34/557 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as COSV55770406; called by muse, mutect2
- KIF27 | c.1794A>T p.R598S | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV52825754; called by muse, mutect2, varscan2
- KLHL1 | c.1753A>T p.S585C | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64767887; called by muse, mutect2, varscan2
- KLHL20 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 182/598 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52940557; called by muse, mutect2, varscan2
- KLHL6 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100384738, COSV58064813; called by muse, mutect2, varscan2
- KLK4 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60675824, COSV60677017; called by muse, mutect2, varscan2
- KRT6A | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV58104048; called by muse, mutect2
- KRTAP10-8 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 111/565 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV58166017, COSV58166627; called by muse, mutect2, varscan2
- LAMC1 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51133675; called by muse, mutect2, varscan2
- LAMC3 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63088959; called by muse, mutect2
- LARP4B | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1414430676, COSV60220220; called by muse, mutect2
- LELP1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64202309; called by muse, mutect2
- LETMD1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV50396781; called by muse, mutect2, varscan2
- LGALS9 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV56348141; called by muse, mutect2, varscan2
- LGI3 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV60443023; called by muse, mutect2, varscan2
- LHCGR | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54293448; called by muse, mutect2, varscan2
- LILRB1 | c.1631C>A p.S544* (on ENST00000427581; = p.S494* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 90/309 reads (29%) | catalogued as COSV61116402; called by muse, mutect2, varscan2
- LIPK | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68200711; called by muse, varscan2
- LONRF3 | c.1948G>T p.D650Y (on ENST00000371628 / NM_001031855.3; = p.D609Y on NM_024778.5) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100504266, COSV59150402; called by muse, mutect2, varscan2
- LOXL4 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53255527; called by muse, mutect2, varscan2
- LPA | c.4865A>T p.Q1622L | Missense Mutation (SNP) | VAF 229/790 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV60297972; called by muse, mutect2, varscan2
- LRAT | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV60476607; called by muse, mutect2, varscan2
- LRIT2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60565398; called by muse, mutect2, varscan2
- LRIT2 | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 65/157 reads (41%) | catalogued as rs199824710, COSV100258534, COSV60564499; called by muse, mutect2, varscan2
- LRPPRC | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53234833; called by muse, mutect2, varscan2
- LRRC66 | c.2643A>C p.*881Yext*24 | Nonstop Mutation (SNP) | VAF 13/204 reads (6%) | catalogued as COSV58632340; called by muse, mutect2
- LRRC7 | c.3304A>G p.K1102E (on ENST00000651989 / NM_001370785.2; = p.K1069E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50417079; called by muse, mutect2, varscan2
- LTBP1 | c.1102G>T p.G368C (on ENST00000404816 / NM_206943.4; = p.G42C on NM_000627.4) | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63181350, COSV63190597; called by muse, mutect2, varscan2
- LYST | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV67703998; called by muse, mutect2
- LZTS2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64650995; called by muse, mutect2, varscan2
- MAGEC1 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV53569035; called by muse, mutect2, varscan2
- MAML2 | c.2571G>A p.M857I | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs1328736058, COSV73262874; called by muse, mutect2
- MAPK4 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs763078166, COSV68541257; called by muse, mutect2
- MCPH1 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761698331, COSV60910693; called by muse, mutect2, varscan2
- MEF2C | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425521, COSV60926486; called by muse, mutect2, varscan2
- MEP1A | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV57918341; called by muse, mutect2, varscan2
- METTL4 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55247144; called by muse, mutect2, varscan2
- MGAM | c.3422C>A p.S1141Y | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV72073861; called by muse, mutect2, varscan2
- MICAL3 | c.3970G>T p.V1324L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV71588069; called by muse, mutect2
- MMP10 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54245588; called by muse, mutect2
- MMP9 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV64884321; called by muse, mutect2, varscan2
- MNDA | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV63740075; called by muse, mutect2, varscan2
- MRGPRX3 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 25/252 reads (10%) | catalogued as COSV66933290; called by muse, mutect2
- MRPL30 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.299); catalogued as rs773756100, COSV57666628; called by muse, mutect2, varscan2
- MUC16 | c.33710C>A p.S11237* | Nonsense Mutation (SNP) | VAF 60/308 reads (19%) | catalogued as COSV67449711; called by muse, mutect2, varscan2
- MUC21 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs748992183, COSV100888839; called by muse, varscan2
- MUSK | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51878545; called by muse, mutect2, varscan2
- MX2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as rs751048457, COSV58095396; called by muse, mutect2
- MXRA5 | c.2410T>G p.L804V | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54226312; called by muse, mutect2
- MYB | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 120/448 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57196289; called by muse, mutect2, varscan2
- MYH1 | c.4809C>A p.S1603R | Missense Mutation (SNP) | VAF 237/799 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56844561; called by muse, varscan2
- MYH14 | c.3362G>C p.G1121A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV51811558; called by muse, mutect2
- MYO1D | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 56/196 reads (29%) | catalogued as COSV59008301; called by muse, mutect2, varscan2
- MYO1G | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51853360; called by muse, mutect2, varscan2
- MYOM3 | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58390639; called by muse, mutect2, varscan2
- NAGPA | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | PolyPhen benign (0.097); catalogued as COSV56569394; called by muse, mutect2, varscan2
- NBAS | c.5139-1G>T p.X1713_splice | Splice Site (SNP) | VAF 14/120 reads (12%) | catalogued as COSV55714223; called by muse, mutect2
- NBAS | c.4349G>T p.G1450V | Missense Mutation (SNP) | VAF 114/721 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55714234; called by muse, mutect2, varscan2
- NBEA | c.3233C>A p.P1078Q | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.26); catalogued as COSV59764301; called by muse, mutect2, varscan2
- NDST4 | c.1814C>G p.T605R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52110805; called by muse, mutect2, varscan2
- NEDD4 | c.2735A>G p.N912S (on ENST00000508342 / NM_001284338.1; = p.N493S on NM_006154.4) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59059163; called by muse, mutect2, varscan2
- NID1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51615832; called by muse, mutect2, varscan2
- NID1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51615849; called by muse, mutect2, varscan2
- NIPAL3 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50230305; called by muse, mutect2, varscan2
- NLRP14 | c.3251A>T p.E1084V | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV55064700; called by muse, mutect2
- NLRP2 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54752874; called by muse, mutect2, varscan2
- NLRP3 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as CM060243, CM071606, COSV60220950; called by muse, mutect2, varscan2
- NLRP4 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NLRP4 | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56709107, COSV56714256; called by mutect2, varscan2
- NMUR1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.647); catalogued as rs775345754, COSV59403614; called by muse, mutect2, varscan2
- NNMT | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV55473008; called by muse, mutect2
- NNMT | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV55473096; called by muse, mutect2, varscan2
- NOS1AP | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62632536; called by muse, mutect2, varscan2
- NOTCH4 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV66679167, COSV66679207; called by muse, mutect2, varscan2
- NPY2R | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV61527392; called by muse, mutect2, varscan2
- NRSN1 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV65893720; called by muse, mutect2, varscan2
- NTAQ1 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54873826, COSV54876634; called by muse, mutect2, varscan2
- NUF2 | c.276-1G>T p.X92_splice | Splice Site (SNP) | VAF 105/474 reads (22%) | catalogued as COSV54842363; called by muse, mutect2, varscan2
- NUGGC | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV58432879; called by muse, mutect2, varscan2
- NUGGC | c.1886A>G p.K629R | Missense Mutation (SNP) | VAF 69/488 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV58432892; called by muse, mutect2, varscan2
- NUGGC | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV58432905; called by mutect2, varscan2
- NUP58 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750980; called by muse, mutect2, varscan2
- OBSCN | c.16484C>A p.S5495* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as COSV52747622; called by muse, mutect2, varscan2
- OGN | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99363999; called by muse, mutect2, varscan2
- OR13C4 | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.442); catalogued as rs1231005102, COSV52926000; called by muse, mutect2
- OR13C4 | c.343del p.G116Afs*2 | Frame Shift Del (DEL) | VAF 80/730 reads (11%) | catalogued as COSV52926735; called by mutect2, varscan2
- OR14A16 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 140/822 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV62926213; called by muse, mutect2, varscan2
- OR1J4 | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as COSV61589602; called by muse, mutect2
- OR1N2 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 112/951 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65460303; called by muse, mutect2, varscan2
- OR2B11 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 106/484 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV59509455; called by muse, mutect2, varscan2
- OR2C3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63574549; called by muse, mutect2
- OR2G2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 296/1165 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60739619; called by muse, mutect2, varscan2
- OR2G3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60680996; called by muse, mutect2, varscan2
- OR2K2 | c.208G>A p.G70S (on ENST00000374428; = p.G41S on NM_205859.2) | Missense Mutation (SNP) | VAF 24/651 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57016239; called by muse, mutect2
- OR2L3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 134/996 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV63454631; called by muse, varscan2
- OR2M7 | c.257T>A p.L86* | Nonsense Mutation (SNP) | VAF 330/1461 reads (23%) | catalogued as COSV58738152; called by muse, mutect2
- OR2M7 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 123/746 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV58738159; called by muse, mutect2, varscan2
- OR2T10 | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100393641, COSV57896246; called by muse, mutect2, varscan2
- OR2T34 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 260/1317 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV60899780, COSV60900889; called by muse, mutect2, varscan2
- OR2T8 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369963137, COSV60661777; called by muse, varscan2
- OR2W3 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64456220, COSV64456361, COSV64456545; called by muse, mutect2, varscan2
- OR4A15 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 155/700 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV59033850, COSV59034664; called by muse, mutect2, varscan2
- OR4B1 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 24/738 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV58882160; called by muse, mutect2
- OR4D5 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 176/448 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV58305900; called by muse, mutect2, varscan2
- OR4D6 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55659131; called by muse, mutect2, varscan2
- OR51Q1 | c.885T>A p.S295R | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56178029; called by muse, mutect2, varscan2
- OR52B4 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68768633; called by muse, mutect2, varscan2
- OR52K1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 145/732 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV56903092; called by muse, mutect2, varscan2
- OR5K3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 198/975 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV67349767; called by muse, mutect2, varscan2
- OR6C1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101110430, COSV65572776; called by muse, mutect2, varscan2
- OR6K2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 171/601 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV62743167; called by muse, mutect2, varscan2
- OR8J1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57316855; called by muse, mutect2, varscan2
- OSBPL6 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51912195; called by muse, mutect2, varscan2
- OTOA | c.2058+1G>T p.X686_splice (on ENST00000286149; = p.X672_splice on NM_144672.4) | Splice Site (SNP) | VAF 38/270 reads (14%) | catalogued as COSV53750157; called by muse, mutect2, varscan2
- OXSM | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV55000854, COSV99772001; called by muse, mutect2, varscan2
- PALB2 | c.2956G>T p.D986Y | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55162891; called by muse, mutect2, varscan2
- PAPPA2 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 221/906 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62774202; called by muse, mutect2, varscan2
- PAPPA2 | c.4232C>G p.S1411C | Missense Mutation (SNP) | VAF 52/1074 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV62792044; called by muse, mutect2
- PAQR9 | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61417691, COSV61418890; called by muse, mutect2, varscan2
- PARP8 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV55856668; called by muse, mutect2, varscan2
- PCDH10 | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52088555; called by muse, mutect2, varscan2
- PCDHB7 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV50755814, COSV50775321; called by muse, mutect2, varscan2
- PCDHGA8 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs756625630, COSV53908987; called by muse, mutect2, varscan2
- PCDHGA9 | c.2157G>T p.W719C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53909016; called by muse, mutect2, varscan2
- PCYT1B | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 287/747 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63264203; called by muse, mutect2, varscan2
- PDE8B | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 28/976 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53732987; called by muse, mutect2
- PDGFA | c.580G>T p.G194* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV63279250; called by muse, mutect2
- PDILT | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 56/442 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs747898472, COSV56699985, COSV56701372; called by muse, mutect2, varscan2
- PDZD9 | c.395T>G p.V132G (on ENST00000424898 / NM_001363519.1; = p.V72G on NM_173806.4) | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV51671039; called by muse, mutect2, varscan2
- PDZRN3 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747778714, COSV55192349, COSV99731424; called by muse, mutect2, varscan2
- PDZRN3 | c.2777G>C p.R926P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55192373; called by muse, mutect2, varscan2
- PECR | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54733625; called by muse, mutect2, varscan2
- PHLDA1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV56996736, COSV56996832; called by muse, mutect2, varscan2
- PI4KB | c.300G>T p.E100D (on ENST00000368873 / NM_001369623.1; = p.E112D on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.584); catalogued as COSV55015593; called by muse, mutect2, varscan2
- PIP5K1A | c.343G>T p.V115L (on ENST00000368888 / NM_001135638.2; = p.V102L on NM_003557.3) | Missense Mutation (SNP) | VAF 123/459 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV62957543; called by muse, mutect2, varscan2
- PKHD1L1 | c.8535C>A p.H2845Q | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65738596; called by muse, mutect2, varscan2
- PKNOX2 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53541886; called by muse, mutect2, varscan2
- PLB1 | c.4050C>A p.F1350L | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59820331; called by muse, varscan2
- PLCB1 | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100569763; called by muse, mutect2, varscan2
- PLCE1 | c.2575C>A p.Q859K | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV99593866; called by muse, mutect2, varscan2
- PLCE1 | c.2576A>G p.Q859R | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99593873; called by muse, mutect2, varscan2
- PLPPR4 | c.926A>C p.Y309S | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64564647; called by muse, mutect2
- PLXND1 | c.4994-1G>C p.X1665_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV60709986; called by muse, mutect2, varscan2
- PPP1R12B | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61113940; called by muse, mutect2, varscan2
- PPP2R1A | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59042818; called by muse, mutect2, varscan2
- PPP3R2 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV62451450; called by muse, mutect2, varscan2
- PPP4R3A | c.2336G>T p.G779V (on ENST00000554943 / NM_001366432.1; = p.G766V on NM_001284280.1) | Missense Mutation (SNP) | VAF 59/491 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as COSV61503680; called by muse, mutect2, varscan2
- PRAMEF19 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 105/1450 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs763111416; called by muse, mutect2
- PRDM5 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53356651; called by muse, mutect2, varscan2
- PRELP | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV58115097, COSV58116639; called by muse, mutect2, varscan2
- PRKCB | c.528C>A p.L176= | Splice Region (SNP) | VAF 34/216 reads (16%) | catalogued as COSV57768867; called by muse, mutect2, varscan2
- PRKD1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59560745; called by muse, mutect2
- PRPF38B | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 59/179 reads (33%) | catalogued as COSV64223543; called by muse, mutect2, varscan2
- PRPS1L1 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 170/605 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV72649831; called by muse, mutect2, varscan2
- PSD | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV50042276, COSV50065773; called by muse, mutect2, varscan2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 99/636 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2, varscan2
- PTAFR | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536158, COSV59536571; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>C p.V692L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.84); catalogued as COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- PTGFR | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV66114511, COSV66116048; called by muse, mutect2, varscan2
- PTGFRN | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 60/863 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV67797915; called by muse, mutect2
- PTPRD | c.3745C>A p.P1249T | Missense Mutation (SNP) | VAF 46/550 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV61931781; called by muse, mutect2
- PTPRZ1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 172/549 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1029352780, COSV66431656; called by muse, mutect2, varscan2
- PUM2 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57578403; called by muse, mutect2, varscan2
- PUM3 | c.1189-1G>T p.X397_splice | Splice Site (SNP) | VAF 16/180 reads (9%) | catalogued as COSV67395793; called by muse, mutect2
- PXDN | c.2463G>T p.W821C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53228074; called by muse, mutect2
- QTRT1 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748388439, COSV51550332, COSV99139017; called by muse, mutect2, varscan2
- R3HDM1 | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51521501; called by muse, mutect2, varscan2
- RAB3C | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 81/578 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as COSV51432144; called by muse, mutect2, varscan2
- RAB3GAP2 | c.149del p.G50Efs*41 | Frame Shift Del (DEL) | VAF 56/228 reads (25%) | catalogued as COSV52966745; called by mutect2, pindel, varscan2
- RABGEF1 | c.776G>T p.R259L (on ENST00000439720 / NM_001287061.2; = p.R246L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53161033; called by muse, mutect2, varscan2
- RABL3 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 178/787 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV56335162; called by muse, mutect2, varscan2
- RAG1 | c.2683G>T p.V895L | Missense Mutation (SNP) | VAF 57/702 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55024101; called by muse, mutect2
- RALGPS1 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52217279; called by muse, mutect2
- RALGPS2 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV100243628; called by muse, mutect2, varscan2
- RANGAP1 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV62362614; called by muse, varscan2
- RAPGEF2 | c.3487G>T p.V1163L | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52425451; called by muse, mutect2, varscan2
- RAPGEF3 | c.848G>T p.W283L (on ENST00000389212; = p.W241L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50198845; called by muse, mutect2, varscan2
- RASGRF2 | c.1996C>A p.L666M | Missense Mutation (SNP) | VAF 256/1134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54124012; called by muse, varscan2
- RASGRF2 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 125/540 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54124024; called by muse, varscan2
- RASSF2 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RBBP6 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV60503656; called by muse, mutect2, varscan2
- RBM47 | c.481A>T p.M161L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55930810; called by muse, mutect2, varscan2
- RBM7 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1197876807, COSV64955434; called by muse, mutect2, varscan2
- RDH16 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV100660177, COSV62457935; called by muse, mutect2, varscan2
- REC114 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58521596; called by muse, mutect2, varscan2
- REG3A | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV59408670; called by muse, varscan2
- RFC3 | c.661A>T p.R221* | Nonsense Mutation (SNP) | VAF 32/179 reads (18%) | catalogued as COSV66296524; called by muse, mutect2, varscan2
- RGS22 | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760394259, COSV62658145; called by muse, mutect2, varscan2
- RHOJ | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs921202045, COSV57456941; called by muse, mutect2, varscan2
- RICTOR | c.4258G>T p.G1420C | Missense Mutation (SNP) | VAF 81/643 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57118145, COSV57121123; called by muse, mutect2, varscan2
- RICTOR | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 81/660 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57118160, COSV99704618; called by muse, mutect2, varscan2
- RIMS1 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442305, COSV53450164; called by muse, mutect2, varscan2
- RIMS2 | c.2233A>G p.I745V (on ENST00000666250 / NM_001348490.2; = p.I553V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51658077; called by muse, mutect2, varscan2
- RIPOR2 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52418052; called by muse, mutect2
- ROR2 | c.1821del p.S608Afs*15 | Frame Shift Del (DEL) | VAF 36/179 reads (20%) | catalogued as COSV65219314; called by mutect2, pindel, varscan2
- RPS6KL1 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as COSV63580733; called by muse, mutect2, varscan2
- RSPO2 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 175/516 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52639444; called by muse, mutect2, varscan2
- RTTN | c.5312C>T p.T1771I | Missense Mutation (SNP) | VAF 20/674 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV55342008; called by muse, mutect2
- RUVBL1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59475136; called by muse, mutect2, varscan2
- SAMHD1 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs761616206, COSV53428585; called by muse, mutect2, varscan2
- SCAF11 | c.2711G>T p.G904V | Missense Mutation (SNP) | VAF 149/339 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65475262; called by muse, mutect2, varscan2
- SCG2 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 199/881 reads (23%) | catalogued as COSV100544872, COSV59539229; called by muse, mutect2, varscan2
- SCN1A | c.2509G>T p.G837C (on ENST00000303395 / NM_001202435.3; = p.G826C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV57662590; called by muse, mutect2, varscan2
- SCN9A | c.2822A>T p.Q941L (on ENST00000303354; = p.Q930L on NM_002977.3) | Missense Mutation (SNP) | VAF 137/1130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV57602235; called by muse, mutect2, varscan2
- SCRN1 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54128739; called by muse, mutect2, varscan2
- SDK1 | c.3625G>T p.V1209L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV67358609; called by mutect2, varscan2
- SEC13 | c.258G>C p.W86C (on ENST00000350697 / NM_183352.3; = p.W89C on NM_030673.4) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61601343, COSV61602328; called by muse, mutect2, varscan2
- SEC31A | c.3500C>A p.T1167N (on ENST00000355196 / NM_001318120.1; = p.T1128N on NM_016211.4) | Missense Mutation (SNP) | VAF 75/444 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV52342095; called by muse, mutect2, varscan2
- SEMA3A | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as COSV54863214, COSV54870165; called by muse, mutect2, varscan2
- SERPINA9 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 165/622 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54073061; called by muse, varscan2
- SERPINA9 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 294/1283 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV54073079; called by muse, varscan2
- SERPINB12 | c.504T>A p.G168= | Splice Region (SNP) | VAF 46/603 reads (8%) | catalogued as COSV54032267; called by muse, mutect2
- SETBP1 | c.3815G>C p.S1272T | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56314588; called by muse, varscan2
- SH3GL3 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559656402, COSV61053890, COSV61056992; called by muse, varscan2
- SHOC1 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV59498205; called by muse, mutect2, varscan2
- SHPRH | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV51605525; called by muse, mutect2, varscan2
- SIGLEC10 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 33/63 reads (52%) | catalogued as COSV59479537; called by muse, mutect2, varscan2
- SIGLEC8 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58472444; called by muse, mutect2, varscan2
- SIGLEC9 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51582875; called by muse, mutect2, varscan2
- SKAP2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 17/129 reads (13%) | catalogued as COSV61721770; called by muse, mutect2, varscan2
- SLC10A2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV55357451; called by muse, mutect2
- SLC10A7 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV53880821; called by muse, mutect2, varscan2
- SLC12A1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 152/378 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57708450; called by muse, mutect2, varscan2
- SLC17A9 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1283808937, COSV64846909; called by muse, mutect2
- SLC22A6 | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as COSV64559895; called by muse, mutect2, varscan2
- SLC27A2 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 30/652 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV51057750; called by muse, mutect2
- SLC30A3 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV51984206; called by muse, mutect2, varscan2
- SLC44A1 | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 119/485 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV58262544; called by muse, mutect2, varscan2
- SLC4A3 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs766023938, COSV56091989; called by muse, mutect2, varscan2
- SLC5A11 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 100/468 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61740384; called by muse, mutect2, varscan2
- SLC5A7 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50889271; called by muse, mutect2, varscan2
- SLC6A19 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58669857; called by muse, mutect2, varscan2
- SLC6A5 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV54224033, COSV54224296; called by muse, mutect2, varscan2
- SLCO2B1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV56933378; called by muse, mutect2, varscan2
- SLIT1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56581393; called by muse, mutect2, varscan2
- SLITRK6 | c.1355C>A p.P452Q | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV68389526; called by muse, mutect2, varscan2
- SMARCAD1 | c.3020G>T p.G1007V | Missense Mutation (SNP) | VAF 97/514 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV62773170; called by muse, mutect2, varscan2
- SMC4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58445575; called by muse, mutect2, varscan2
- SMOC1 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 103/479 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1455506717, COSV62759766, COSV62760557; called by muse, mutect2, varscan2
- SMURF1 | c.1918T>G p.L640V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62815787; called by mutect2, varscan2
- SNIP1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 75/705 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56165765; called by muse, mutect2, varscan2
- SORCS3 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 236/834 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100865177, COSV63803722; called by muse, mutect2, varscan2
- SOX5 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV58620713; called by muse, mutect2
- SPEF2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61544933; called by muse, mutect2, varscan2
- SPEG | c.7937G>T p.R2646L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs201143360, COSV56664385, COSV56671387; called by mutect2, varscan2
- SPN | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.423); catalogued as COSV64070009; called by muse, mutect2, varscan2
- SPRR1B | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 122/563 reads (22%) | catalogued as COSV61067471; called by muse, mutect2, varscan2
- SPTBN1 | c.6790G>T p.V2264L | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV61686131; called by muse, mutect2
- SRGAP2 | c.1646C>T p.A549V (on ENST00000624873 / NM_001170637.4; = p.A550V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55333992; called by muse, mutect2, varscan2
- SRGAP2 | c.3161G>T p.G1054V (on ENST00000624873 / NM_001170637.4; = p.G1055V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV55334005; called by muse, mutect2, varscan2
- STARD13 | c.839G>T p.R280L (on ENST00000336934 / NM_001243476.3; = p.R162L on NM_052851.3) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV55227890; called by muse, mutect2
- STARD13 | c.464G>T p.R155L (on ENST00000336934 / NM_001243476.3; = p.R37L on NM_052851.3) | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55227681, COSV55227908; called by muse, mutect2, varscan2
- STARD7 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV61525174; called by muse, mutect2, varscan2
- STEAP4 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as COSV57328271; called by muse, mutect2, varscan2
- STIM1 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 92/384 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56152127; called by muse, mutect2, varscan2
- STK31 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 81/720 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63454440; called by muse, mutect2, varscan2
- STPG2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 81/418 reads (19%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV54787871; called by muse, mutect2, varscan2
- STXBP1 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 49/455 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1462181047, COSV64812224; called by muse, mutect2, varscan2
- STXBP4 | c.74T>C p.I25T | Missense Mutation (SNP) | VAF 25/422 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs763415470, COSV54840450; called by muse, mutect2
- SULT2A1 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV55764269; called by muse, mutect2, varscan2
- SYCP2L | c.1541C>A p.T514N | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV51650478; called by muse, mutect2
- SYNPO2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs914334727, COSV61107476; called by muse, mutect2, varscan2
- SYNPO2 | c.2045G>T p.G682V | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61107491; called by muse, mutect2
- SYT6 | c.1399G>T p.V467L (on ENST00000610222 / NM_001366225.1; = p.V382L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV65772698; called by muse, mutect2, varscan2
- SYTL2 | c.252A>T p.A84= | Splice Region (SNP) | VAF 151/446 reads (34%) | catalogued as COSV60356417; called by muse, mutect2, varscan2
- TAF1L | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 142/513 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54259118, COSV99644232; called by muse, mutect2, varscan2
- TAF1L | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 143/521 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV54262769, COSV99644233; called by muse, mutect2, varscan2
- TAS1R1 | c.2439C>A p.Y813* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV59839437; called by muse, mutect2
- TBX22 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV64785128; called by muse, mutect2
- TBX3 | c.1069G>T p.A357S (on ENST00000257566 / NM_016569.4; = p.A337S on NM_005996.4) | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as COSV57469656; called by muse, mutect2, varscan2
- TBX5 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59858835; called by muse, mutect2
- TCF7L2 | c.1319-2A>T p.X440_splice (on ENST00000355995 / NM_001367943.1; = p.X417_splice on NM_030756.5) | Splice Site (SNP) | VAF 44/357 reads (12%) | catalogued as COSV99525401; called by muse, mutect2, varscan2
- TENM2 | c.1729C>A p.P577T (on ENST00000518659 / NM_001122679.2; = p.P345T on NM_001080428.3) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV69124046; called by muse, mutect2, varscan2
- TENM4 | c.2570G>T p.C857F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53612327; called by muse, mutect2, varscan2
- TESPA1 | c.889C>T p.R297* (on ENST00000316577 / NM_001098815.3; = p.R159* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 120/303 reads (40%) | catalogued as rs764857918, COSV57257521; called by muse, mutect2, varscan2
- TET1 | c.5352G>T p.K1784N | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1454252323, COSV65382496; called by muse, mutect2
- TET1 | c.5698G>T p.G1900C | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65382501; called by muse, mutect2
- TEX13B | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57202254; called by muse, mutect2, varscan2
- TEX2 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 53/194 reads (27%) | catalogued as COSV51978037; called by muse, mutect2, varscan2
- TFAP2B | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV53825533; called by muse, mutect2, varscan2
- TFPT | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV58084653; called by muse, mutect2, varscan2
- TG | c.7620C>A p.Y2540* | Nonsense Mutation (SNP) | VAF 92/252 reads (37%) | catalogued as COSV55067077; called by muse, mutect2, varscan2
- TGFBR3 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 62/340 reads (18%) | catalogued as COSV53022438; called by muse, mutect2, varscan2
- TGM4 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV56092980; called by muse, mutect2, varscan2
- THSD7A | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV70261105; called by muse, mutect2, varscan2
- TIGD4 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100427862, COSV58549072; called by muse, mutect2, varscan2
- TIMELESS | c.3454G>T p.E1152* | Nonsense Mutation (SNP) | VAF 145/368 reads (39%) | catalogued as COSV57509473; called by muse, mutect2, varscan2
- TKTL2 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54917715, COSV54919539; called by muse, mutect2, varscan2
- TLL1 | c.1963A>T p.R655* | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as COSV50263459, COSV50321640; called by muse, mutect2, varscan2
- TNC | c.3435T>G p.Y1145* | Nonsense Mutation (SNP) | VAF 79/759 reads (10%) | catalogued as COSV60781231; called by muse, mutect2, varscan2
- TNRC6C | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs1385285782, COSV56941304; called by muse, mutect2, varscan2
- TOPORS | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV62116305; called by muse, mutect2
- TPH2 | c.1071C>G p.C357W | Missense Mutation (SNP) | VAF 13/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61590797; called by muse, mutect2
- TPO | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.156); catalogued as COSV61096265; called by muse, mutect2, varscan2
- TRAM1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV51596845; called by muse, mutect2, varscan2
- TRAM1L1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV60291369; called by muse, mutect2, varscan2
- TRANK1 | c.8203G>A p.G2735S | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs765419817, COSV57143035, COSV57160597; called by muse, mutect2, varscan2
- TRIB2 | c.1001T>A p.M334K | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.05); catalogued as COSV99330952; called by muse, mutect2, varscan2
- TRIB2 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV50223936, COSV99330959; called by muse, mutect2, varscan2
- TRIM55 | c.1236G>A p.Q412= | Splice Region (SNP) | VAF 41/221 reads (19%) | catalogued as COSV99396586; called by muse, mutect2, varscan2
- TRIM55 | c.1236+1G>T p.X412_splice | Splice Site (SNP) | VAF 41/218 reads (19%) | catalogued as COSV52545690, COSV99396591; called by muse, mutect2, varscan2
- TRIM75P | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.421); catalogued as COSV72295808; called by muse, mutect2, varscan2
- TRIML1 | c.1386C>A p.C462* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV60193516; called by muse, mutect2, varscan2
- TRMT2B | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV58618627; called by muse, mutect2, varscan2
- TRPM4 | c.2953G>T p.V985L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53259986; called by muse, mutect2, varscan2
- TRPV5 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV54683514; called by muse, mutect2, varscan2
- TSPAN33 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV56825583; called by muse, mutect2, varscan2
- TTN | c.63115A>G p.I21039V (on ENST00000591111; = p.I13615V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | PolyPhen benign (0.003); catalogued as COSV59914871; called by muse, mutect2, varscan2
- TXNDC12 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 53/432 reads (12%) | catalogued as COSV65412962; called by muse, mutect2, varscan2
- UCMA | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66321313, COSV66321927; called by muse, mutect2, varscan2
- UGDH | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV57096859; called by muse, mutect2, varscan2
- UGT2A1 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54138765; called by muse, mutect2, varscan2
- UGT2A3 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52359053; called by muse, mutect2, varscan2
- UMODL1 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs150059583, COSV61159437; called by muse, mutect2, varscan2
- UNC13C | c.2645T>A p.M882K | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV52848094; called by muse, mutect2, varscan2
- UNC5B | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV58974958; called by muse, mutect2, varscan2
- USF3 | c.4761C>A p.N1587K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV57070355; called by muse, mutect2, varscan2
- USH2A | c.6949G>T p.G2317C | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335022; called by muse, mutect2, varscan2
- USH2A | c.1493C>A p.T498N | Missense Mutation (SNP) | VAF 151/558 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV56335038; called by muse, mutect2, varscan2
- USHBP1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs528877755, COSV53102475; called by muse, mutect2, varscan2
- USP34 | c.5315G>T p.R1772M | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV68398936; called by muse, mutect2, varscan2
- USP6 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51476237; called by muse, mutect2, varscan2
- USP8 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56162742; called by muse, mutect2, varscan2
- VCAN | c.8380G>C p.E2794Q | Missense Mutation (SNP) | VAF 36/507 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs1258524498, COSV54098501; called by muse, mutect2
- VPS13C | c.2662A>G p.T888A (on ENST00000644861 / NM_020821.3; = p.T845A on NM_017684.5) | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51126776; called by muse, mutect2, varscan2
- VPS16 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66792615; called by muse, mutect2, varscan2
- VPS35 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54477333; called by muse, mutect2, varscan2
- VSNL1 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 45/453 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV54597763; called by muse, mutect2
- VSTM2A | c.372A>T p.L124F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56492547; called by muse, mutect2, varscan2
- VWA5A | c.1625+1G>C p.X542_splice | Splice Site (SNP) | VAF 43/416 reads (10%) | catalogued as COSV64412069; called by muse, mutect2
- VWF | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54613271; called by muse, mutect2, varscan2
- WARS2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 75/714 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV52476213; called by muse, mutect2, varscan2
- WDR27 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 177/596 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61205048; called by muse, mutect2, varscan2
- WDR36 | c.1610-1G>T p.X537_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV72605091; called by mutect2, varscan2
- WNK4 | c.2117A>C p.D706A | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55901944; called by muse, mutect2
- YARS2 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV61401423; called by muse, mutect2, varscan2
- YIPF7 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60656114; called by muse, mutect2, varscan2
- ZBED4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53464082; called by muse, mutect2, varscan2
- ZBTB21 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.963); catalogued as COSV60403299, COSV60404906; called by muse, mutect2
- ZC3H6 | c.2663C>G p.P888R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59666282; called by muse, mutect2, varscan2
- ZEB1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 134/560 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs963030640, COSV100313658, COSV58037936; called by muse, mutect2, varscan2
- ZFHX4 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV50549966; called by muse, mutect2
- ZFHX4 | c.7613T>C p.M2538T | Missense Mutation (SNP) | VAF 104/634 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50550614; called by muse, mutect2, varscan2
- ZFPM2 | c.2114A>G p.H705R | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65872742; called by muse, mutect2, varscan2
- ZMYND11 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV59076674; called by muse, mutect2, varscan2
- ZNF236 | c.2173G>T p.G725C | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53483373; called by muse, mutect2
- ZNF268 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99934759; called by muse, mutect2, varscan2
- ZNF268 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99934762; called by muse, mutect2, varscan2
- ZNF285 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | catalogued as COSV58408173; called by muse, mutect2, varscan2
- ZNF292 | c.2751G>T p.L917F | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.188); catalogued as COSV60536307; called by muse, mutect2, varscan2
- ZNF592 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV55435363; called by muse, mutect2, varscan2
- ZNF680 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV59014178; called by muse, mutect2
- ZNF683 | c.1252C>G p.R418G (on ENST00000403843; = p.R398G on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62873582, COSV62874562; called by muse, mutect2, varscan2
- ZNF713 | c.198G>T p.E66D (on ENST00000633730 / NM_001366796.2; = p.E79D on NM_182633.3) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68887878; called by muse, mutect2, varscan2
- ZNF804B | c.1635G>T p.W545C | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as COSV60818633; called by muse, mutect2, varscan2
- ZNF831 | c.4238C>G p.T1413S | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV64037978; called by muse, varscan2
- ZP1 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV53923401, COSV53923449; called by muse, mutect2, varscan2
- AATF | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.478); called by muse, mutect2
- ACVR2A | c.1310dup p.R438Efs*19 | Frame Shift Ins (INS) | VAF 59/307 reads (19%) | called by mutect2, varscan2
- BIRC6 | c.4685_4693del p.E1562_P1565delinsA | In Frame Del (DEL) | VAF 45/325 reads (14%) | called by mutect2, pindel, varscan2
- CUBN | c.255C>T p.I85= | Splice Region (SNP) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- FCGBP | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FNBP4 | c.343del p.D115Tfs*13 | Frame Shift Del (DEL) | VAF 85/379 reads (22%) | called by mutect2, pindel, varscan2
- FRG2C | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- HP1BP3 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHG1 | c.672G>C p.G224= | Splice Region (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGKV2D-24 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- KRTAP26-1 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 21/520 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2
- LILRA6 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- MIXL1 | c.502del p.T168Rfs*4 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- PRH2 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 63/759 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2
- RSPH10B | c.184del p.Q62Kfs*17 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | called by mutect2, varscan2
- RTL4 | c.801_802delinsA p.P268Qfs*60 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | called by pindel, varscan2*
- SAMD9L | c.465del p.K155Nfs*2 | Frame Shift Del (DEL) | VAF 341/1263 reads (27%) | called by mutect2, pindel, varscan2
- SLC6A9 | c.24dup p.M9Dfs*141 | Frame Shift Ins (INS) | VAF 14/147 reads (10%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 112/772 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2
- STAB2 | c.5294dup p.L1765Ffs*29 | Frame Shift Ins (INS) | VAF 145/426 reads (34%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1044G>T p.W348C | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TLL2 | c.522dup p.S175Efs*7 | Frame Shift Ins (INS) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRAV13-1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRAV22 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TRBV27 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- TRBV4-2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- U2AF2 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); called by mutect2, varscan2
- VPS13B | c.7232_7245del p.I2411Rfs*23 | Frame Shift Del (DEL) | VAF 26/220 reads (12%) | called by mutect2, pindel
- WASHC2C | c.3138G>T p.R1046S (on ENST00000336378; = p.R1025S on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/546 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WDR35 | c.2616_2617del p.C872* (on ENST00000345530 / NM_001006657.2; = p.C861* on NM_020779.4) | Nonsense Mutation (DEL) | VAF 81/344 reads (24%) | called by pindel, varscan2
- ZFHX3 | c.536dup p.K180Qfs*30 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- ZNF322 | c.1112C>A p.T371K | Missense Mutation (SNP) | VAF 64/1236 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- ACRBP | c.159C>A p.T53= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV57523232; called by muse, mutect2, varscan2
- ADCY8 | c.3126C>A p.A1042= | Silent (SNP) | VAF 124/595 reads (21%) | catalogued as COSV53898358, COSV53911273; called by muse, mutect2, varscan2
- ADPRHL1 | c.72G>A p.K24= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV60260782; called by muse, varscan2
- AGBL1 | c.2272C>A p.R758= | Silent (SNP) | VAF 91/267 reads (34%) | catalogued as COSV66850612, COSV66852202; called by muse, mutect2, varscan2
- ALDH1L1 | c.744G>C p.T248= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV56411317, COSV56415451; called by muse, mutect2, varscan2
- ANO6 | c.2056C>T p.L686= | Silent (SNP) | VAF 139/331 reads (42%) | catalogued as COSV57657696; called by muse, mutect2, varscan2
- APOB | c.3144C>A p.T1048= | Silent (SNP) | VAF 34/352 reads (10%) | catalogued as COSV51925700; called by muse, mutect2, varscan2
- ARHGAP6 | c.1761C>A p.I587= | Silent (SNP) | VAF 157/388 reads (40%) | catalogued as COSV57292426, COSV57304386; called by muse, mutect2, varscan2
- ARHGEF28 | c.2484A>T p.A828= | Silent (SNP) | VAF 106/462 reads (23%) | catalogued as COSV55248680; called by muse, mutect2, varscan2
- ARHGEF28 | c.3630C>T p.A1210= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV55248694; called by muse, mutect2, varscan2
- ASB15 | c.324C>A p.T108= | Silent (SNP) | VAF 99/385 reads (26%) | catalogued as COSV99306298; called by muse, mutect2, varscan2
- BBS9 | c.2262G>A p.A754= (on ENST00000242067 / NM_001348036.1; = p.A714= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as rs751886707, COSV54158541; called by muse, mutect2
- BEND2 | c.1188C>A p.G396= | Silent (SNP) | VAF 97/250 reads (39%) | catalogued as COSV66215217, COSV66215543; called by muse, mutect2, varscan2
- BNIP2 | c.765A>T p.T255= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV51105222; called by muse, mutect2, varscan2
- BPIFB1 | c.93C>T p.L31= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs766101557, COSV53605360; called by muse, mutect2, varscan2
- BRINP3 | c.396G>T p.G132= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as COSV66515015; called by muse, mutect2, varscan2
- C1QB | c.141C>A p.P47= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV59245084; called by muse, mutect2, varscan2
- C9orf131 | c.3216C>A p.P1072= | Silent (SNP) | VAF 147/625 reads (24%) | catalogued as COSV56609850; called by muse, mutect2, varscan2
- CALHM2 | c.9C>A p.A3= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV53294521; called by muse, mutect2, varscan2
- CD109 | c.294A>T p.A98= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV54646080; called by muse, mutect2, varscan2
- CD22 | c.2220C>A p.A740= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs1389878115, COSV50049863, COSV50055705; called by muse, mutect2
- CNTN2 | c.807C>A p.P269= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs926391066, COSV59348457; called by muse, mutect2, varscan2
- CNTN6 | c.1980A>C p.A660= | Silent (SNP) | VAF 52/198 reads (26%) | catalogued as COSV63163799; called by muse, mutect2, varscan2
- COBL | c.1209G>T p.T403= | Silent (SNP) | VAF 59/173 reads (34%) | catalogued as COSV54339823, COSV54353011; called by muse, mutect2, varscan2
- COL22A1 | c.1431C>A p.S477= | Silent (SNP) | VAF 150/361 reads (42%) | catalogued as COSV57326454; called by muse, mutect2, varscan2
- COL3A1 | c.3381G>A p.Q1127= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as COSV58582992; called by muse, mutect2, varscan2
- CPED1 | c.2838A>T p.L946= | Silent (SNP) | VAF 265/824 reads (32%) | catalogued as rs760984728, COSV100120268; called by muse, mutect2, varscan2
- CSH2 | c.372C>G p.A124= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100400163; called by muse, mutect2, varscan2
- CSMD1 | c.6504G>T p.P2168= (on ENST00000520002; = p.P2167= on NM_033225.6) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV59289747, COSV59322456; called by muse, mutect2, varscan2
- CSMD3 | c.2877A>T p.S959= (on ENST00000297405 / NM_001363185.1; = p.S855= on NM_052900.3) | Silent (SNP) | VAF 23/219 reads (11%) | catalogued as COSV52116045; called by muse, mutect2, varscan2
- CYB561A3 | c.222G>C p.G74= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV53651009; called by muse, mutect2, varscan2
- DACH2 | c.390C>A p.I130= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV64163065; called by muse, mutect2, varscan2
- DUSP15 | c.87A>T p.T29= (on ENST00000278979 / NM_001320479.1; = p.T32= on NM_080611.4) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54065122; called by muse, mutect2
- ELOVL3 | c.453A>T p.T151= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV64174185; called by muse, mutect2, varscan2
- ERN2 | c.1155A>G p.A385= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV56831909; called by muse, mutect2, varscan2
- ESR1 | c.828C>A p.G276= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as rs1296595449, COSV52783514; called by muse, mutect2, varscan2
- FAM135B | c.681C>T p.Y227= | Silent (SNP) | VAF 34/244 reads (14%) | catalogued as COSV52709185; called by muse, varscan2
- FAM71D | c.1056C>T p.T352= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as COSV61294783; called by muse, mutect2, varscan2
- FAT3 | c.4860A>T p.L1620= | Silent (SNP) | VAF 165/481 reads (34%) | catalogued as COSV53082578; called by muse, mutect2, varscan2
- FCRLA | c.252G>A p.Q84= (on ENST00000367959; = p.Q61= on NM_032738.4) | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as COSV52684637; called by muse, varscan2
- FCRLA | c.297C>A p.S99= (on ENST00000367959; = p.S76= on NM_032738.4) | Silent (SNP) | VAF 47/191 reads (25%) | catalogued as COSV99375741; called by muse, varscan2
- GABRB1 | c.1266G>T p.G422= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs773055387, COSV54972792; called by muse, mutect2, varscan2
- GABRR1 | c.747C>T p.L249= | Silent (SNP) | VAF 14/494 reads (3%) | catalogued as COSV65618876; called by muse, mutect2
- GPR132 | c.81C>A p.G27= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV61677663; called by muse, mutect2, varscan2
- GRM3 | c.627C>T p.N209= | Silent (SNP) | VAF 36/229 reads (16%) | catalogued as COSV64468098; called by muse, mutect2, varscan2
- GRM8 | c.2367C>T p.T789= | Silent (SNP) | VAF 22/276 reads (8%) | catalogued as COSV58807183; called by muse, mutect2
- GZMH | c.636C>A p.A212= | Silent (SNP) | VAF 30/202 reads (15%) | catalogued as COSV53537758; called by mutect2, varscan2
- IFT80 | c.1521A>T p.T507= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV58445814; called by muse, mutect2, varscan2
- IGKV1-6 | c.96C>A p.S32= | Silent (SNP) | VAF 74/316 reads (23%) | catalogued as rs769768893; called by muse, varscan2
- IGKV5-2 | c.21C>G p.L7= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- IL27RA | c.564G>T p.L188= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV54599375; called by muse, mutect2, varscan2
- INSC | c.1023G>T p.R341= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as COSV65409114; called by muse, mutect2, varscan2
- INTS2 | c.2028C>T p.P676= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV52151340; called by muse, mutect2, varscan2
- ITIH1 | c.1311C>T p.H437= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV56252820; called by muse, mutect2, varscan2
- ITIH2 | c.1482C>A p.S494= | Silent (SNP) | VAF 66/448 reads (15%) | catalogued as COSV64432194; called by muse, mutect2, varscan2
- KCNK18 | c.315C>T p.S105= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as COSV57971140; called by muse, mutect2, varscan2
- KCTD3 | c.663G>C p.T221= | Silent (SNP) | VAF 122/625 reads (20%) | catalogued as COSV52064631; called by muse, mutect2, varscan2
- KIRREL3 | c.1401C>T p.R467= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV69383744; called by mutect2, varscan2
- KRT5 | c.1281T>C p.D427= | Silent (SNP) | VAF 132/311 reads (42%) | catalogued as COSV52859265; called by muse, mutect2, varscan2
- LAMA2 | c.1485A>T p.G495= | Silent (SNP) | VAF 48/199 reads (24%) | catalogued as COSV70340333; called by muse, mutect2, varscan2
- LBP | c.864G>T p.T288= | Silent (SNP) | VAF 46/302 reads (15%) | catalogued as COSV54138957, COSV54139604; called by muse, varscan2
- LCE3D | c.6C>A p.S2= | Silent (SNP) | VAF 48/302 reads (16%) | catalogued as COSV64230585; called by muse, varscan2
- LCE4A | c.78C>T p.P26= | Silent (SNP) | VAF 62/445 reads (14%) | catalogued as COSV59266441; called by muse, mutect2, varscan2
- LGI2 | c.759C>T p.N253= | Silent (SNP) | VAF 56/370 reads (15%) | catalogued as COSV66122481, COSV66124315; called by muse, varscan2
- LHX9 | c.426C>A p.A142= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV61327373; called by muse, mutect2, varscan2
- LIG4 | c.2032C>T p.L678= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV63596538; called by muse, mutect2, varscan2
- LRRTM1 | c.825G>T p.V275= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV54438791; called by muse, mutect2, varscan2
- LRRTM4 | c.1164C>T p.T388= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV69139170, COSV69141054; called by muse, mutect2, varscan2
- LSAMP | c.240G>T p.L80= | Silent (SNP) | VAF 51/275 reads (19%) | catalogued as COSV61278341; called by muse, mutect2, varscan2
- MAGEB6B | c.843G>A p.A281= | Silent (SNP) | VAF 122/218 reads (56%) | catalogued as COSV69689749; called by muse, mutect2, varscan2
- MAN2A1 | c.1452G>C p.S484= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV54846921, COSV54847689; called by muse, mutect2
- MARK1 | c.204G>A p.K68= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as COSV65065948; called by muse, mutect2
- MGAM | c.1848G>T p.A616= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as COSV72073859; called by muse, mutect2, varscan2
- MGAM | c.4527C>A p.T1509= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV72073863; called by muse, mutect2, varscan2
- MID1IP1 | c.96G>A p.V32= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs756537342, COSV61230421; called by muse, mutect2, varscan2
- MSC | c.585T>A p.V195= | Silent (SNP) | VAF 328/985 reads (33%) | catalogued as COSV57696210; called by muse, mutect2, varscan2
- MUC17 | c.6198A>C p.T2066= | Silent (SNP) | VAF 60/363 reads (17%) | catalogued as COSV60281720; called by muse, mutect2, varscan2
- MYH2 | c.366C>T p.F122= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs1413745639, COSV55432855, COSV55449267; called by muse, mutect2, varscan2
- MYOM3 | c.3837C>T p.H1279= | Silent (SNP) | VAF 64/562 reads (11%) | catalogued as rs766135314, COSV58390623; called by muse, mutect2, varscan2
- NDRG2 | c.843C>A p.T281= (on ENST00000298687 / NM_001354570.1; = p.T267= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV53871883; called by muse, mutect2, varscan2
- NEB | c.6342C>T p.H2114= | Silent (SNP) | VAF 110/444 reads (25%) | catalogued as COSV50831892; called by muse, mutect2, varscan2
- NEGR1 | c.261G>T p.V87= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV60832704; called by muse, mutect2, varscan2
- NETO1 | c.882C>A p.G294= | Silent (SNP) | VAF 102/445 reads (23%) | catalogued as COSV55002464; called by muse, mutect2, varscan2
- NKIRAS2 | c.549C>T p.N183= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV56917486; called by muse, mutect2, varscan2
- NLRC4 | c.69C>A p.I23= | Silent (SNP) | VAF 123/484 reads (25%) | catalogued as COSV61591587; called by muse, mutect2, varscan2
- NOBOX | c.859C>T p.L287= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV56192940; called by muse, mutect2, varscan2
- NPC1 | c.828C>T p.Y276= | Silent (SNP) | VAF 15/280 reads (5%) | catalogued as COSV52576764; called by muse, mutect2
- NPHP3 | c.348G>A p.E116= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV58128787; called by muse, mutect2
- NXF1 | c.576C>T p.N192= | Silent (SNP) | VAF 48/310 reads (15%) | catalogued as COSV53672478; called by muse, mutect2, varscan2
- OGN | c.69C>A p.T23= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV99364006; called by muse, mutect2, varscan2
- OR10S1 | c.276C>A p.P92= | Silent (SNP) | VAF 22/410 reads (5%) | catalogued as COSV73342685; called by muse, mutect2
- OR2C3 | c.456G>A p.G152= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1390540566, COSV63574556; called by muse, mutect2
- OR2G6 | c.333G>A p.E111= | Silent (SNP) | VAF 71/830 reads (9%) | catalogued as rs538615728; called by muse, mutect2
- OR2J2 | c.378T>C p.A126= | Silent (SNP) | VAF 340/2024 reads (17%) | catalogued as COSV65847772; called by muse, mutect2, varscan2
- OR2T1 | c.183C>G p.L61= | Silent (SNP) | VAF 18/706 reads (3%) | catalogued as COSV63541392; called by muse, mutect2
- OR4L1 | c.222C>T p.S74= | Silent (SNP) | VAF 61/506 reads (12%) | catalogued as COSV59849072; called by muse, mutect2, varscan2
- OR51D1 | c.615C>G p.T205= | Silent (SNP) | VAF 256/819 reads (31%) | catalogued as COSV100712441, COSV62913937; called by muse, mutect2, varscan2
- OR5D14 | c.618C>T p.T206= | Silent (SNP) | VAF 35/425 reads (8%) | catalogued as COSV59455610; called by muse, mutect2
- OR5K1 | c.114C>G p.T38= | Silent (SNP) | VAF 207/1162 reads (18%) | catalogued as COSV60303685, COSV60305292; called by muse, mutect2, varscan2
- OR6K3 | c.561C>A p.P187= (on ENST00000368146; = p.P171= on NM_001005327.2) | Silent (SNP) | VAF 207/755 reads (27%) | catalogued as COSV63745378; called by muse, mutect2, varscan2
- OR8B12 | c.72C>A p.I24= | Silent (SNP) | VAF 173/438 reads (39%) | catalogued as COSV60911050, COSV60912472; called by muse, mutect2, varscan2
- OR9G4 | c.936A>G p.T312= | Silent (SNP) | VAF 99/432 reads (23%) | catalogued as COSV57247858; called by muse, mutect2, varscan2
- PACS1 | c.2088G>A p.S696= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as rs546886162, COSV57696624; called by muse, mutect2, varscan2
79 further variants in this file (0 protein-altering or splice-affecting, 65 silent, 14 other) are not listed here.
